Gene-level copy-number profile of tumor specimen TCGA-DM-A28H-01A from TCGA case TCGA-DM-A28H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 50.2 years (18,325 days).
Specimen TCGA-DM-A28H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.56dcd313-6aca-40a2-ba19-b8e49c637ea2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A28H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0066421-a28c-49fa-89de-7d40b1d9c95b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 5,578; copy number 2: 47,691; copy number 3: 3,705; copy number 4: 2,708; copy number 6: 55; copy number 8: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A28H-01A-11D-A16U-01): tumor purity 0.74, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:61,742,477–62,178,675, 1 gene (within-gene range 0–1): PATJ.
- chr1:62,038,842–62,078,859, 4 genes: LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2.
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.
- chr17:11,598,470–12,143,830, 9 genes (within-gene range 0–1): DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.
- chr17:60,677,453–61,392,838, 10 genes (within-gene range 0–2): BCAS3, RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74.
- chr17:72,425,939–72,428,852, 1 gene: AC007639.1.
- chr18:24,932,771–28,177,946, 46 genes: LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 64 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,785,454–7,769,706, 1 gene, copy number 6 (within-gene range 4–6): CAMTA1.
- chr1:7,219,360–9,198,906, 54 genes, copy number 6: RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A.
- chr6:84,421,028–85,257,694, 9 genes, copy number 8: LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1.

Autosomal genes at a single copy (total copy number 1): 5,578. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
